Somatic mutation profile of tumor specimen TCGA-MP-A4TA-01A (aliquot TCGA-MP-A4TA-01A-21D-A24P-08) from TCGA case TCGA-MP-A4TA, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.3 years (27,513 days).
Specimen TCGA-MP-A4TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd1eddb2-1c8f-4645-9938-59f251836806.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4TA-10A (Blood Derived Normal), aliquot TCGA-MP-A4TA-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b80e27d4-4762-4290-b8d4-cf232350bd2e

The open-access MAF lists 385 somatic variants for this specimen: 286 protein-altering or splice-affecting, 91 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 231, Silent 91, Nonsense Mutation 29, Frame Shift Del 10, Splice Region 6, Splice Site 6, RNA 5, Frame Shift Ins 2, Intron 2, Translation Start Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABO | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101505945, COSV101505960; called by muse, mutect2
- ACSM2A | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99525060; called by muse, mutect2
- ADAM18 | c.1125A>T p.K375N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.145); catalogued as COSV99695228; called by muse, mutect2, varscan2
- ADCY1 | c.3016G>T p.A1006S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99811622; called by muse, mutect2, varscan2
- AGK | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100814574; called by muse, mutect2
- AGL | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV54049072, COSV54059254, COSV99648854; called by muse, mutect2, varscan2
- AKAP3 | c.1538C>G p.P513R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.087); catalogued as COSV99961943; called by muse, mutect2, varscan2
- ANKRD26 | c.3097G>C p.A1033P | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs758993716, COSV101063048; called by muse, mutect2
- APCDD1L | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568731652, COSV100953952; called by muse, mutect2, varscan2
- ARFGEF1 | c.4333A>G p.T1445A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV99141471; called by muse, mutect2
- ARHGEF17 | c.3019A>G p.T1007A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV99735148; called by muse, mutect2, varscan2
- ARSG | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.681); catalogued as COSV101477880; called by muse, mutect2, varscan2
- ASPM | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99659924; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1777A>T p.K593* | Nonsense Mutation (SNP) | VAF 14/176 reads (8%) | catalogued as COSV99230697; called by muse, mutect2
- ATP8B4 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV99464528; called by muse, mutect2, varscan2
- AZIN1 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 28/151 reads (19%) | catalogued as COSV100457451; called by muse, mutect2, varscan2
- BLK | c.368+1G>A p.X123_splice | Splice Site (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99377015; called by muse, mutect2
- BTAF1 | c.3220A>G p.K1074E | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs751504087, COSV99795117; called by muse, mutect2, varscan2
- C10orf71 | c.933G>T p.L311F | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as rs1412059292, COSV100109930; called by muse, mutect2, varscan2
- C20orf96 | c.127G>C p.V43L (on ENST00000360321 / NM_153269.3; = p.V42L on NM_080571.1) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100826680; called by muse, mutect2, varscan2
- C6 | c.2532A>T p.E844D | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV99666815; called by muse, mutect2
- CACNA1A | c.1914C>A p.G638= | Splice Region (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100801727; called by muse, mutect2, varscan2
- CACNA2D4 | c.1976A>G p.Y659C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99765346; called by muse, mutect2, varscan2
- CAPZA1 | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV99583010; called by muse, mutect2, varscan2
- CCDC91 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as COSV100081533; called by muse, mutect2, varscan2
- CD2 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV101040321; called by muse, mutect2
- CDH12 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372690961, COSV66392476; called by muse, mutect2, varscan2
- CENPF | c.6010G>T p.V2004L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.16); catalogued as COSV100871604; called by muse, mutect2, varscan2
- CEP250 | c.2900G>T p.G967V | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.165); catalogued as COSV100698832; called by muse, mutect2, varscan2
- CEP250 | c.4756C>T p.Q1586* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100698834, COSV100698852; called by muse, mutect2
- CEP85 | c.2241G>A p.M747I | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99431997; called by muse, mutect2
- CFAP58 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs781111569, COSV100866073, COSV63833793; called by muse, mutect2
- CHEK1 | c.325A>T p.R109* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as COSV99629560; called by muse, mutect2, varscan2
- CNOT1 | c.5415A>G p.G1805= | Splice Region (SNP) | VAF 14/89 reads (16%) | catalogued as COSV99799643; called by muse, mutect2, varscan2
- CNOT1 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100408834; called by muse, mutect2, varscan2
- COL12A1 | c.7802A>T p.D2601V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100485665; called by muse, mutect2, varscan2
- COL22A1 | c.4679C>A p.P1560H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277279; called by muse, mutect2
- COL2A1 | c.3719G>A p.R1240Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs770482348, COSV100475960, COSV100476140; called by muse, mutect2, varscan2
- COL3A1 | c.3493C>T p.P1165S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV100482738; called by muse, mutect2
- COL6A6 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV100650074; called by muse, mutect2, varscan2
- COL6A6 | c.1402A>T p.I468F | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100650076; called by muse, mutect2, varscan2
- COPS8 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100585341; called by muse, mutect2
- CPNE4 | c.1556T>A p.L519Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101456615; called by muse, mutect2
- CSMD1 | c.7559A>T p.Y2520F (on ENST00000520002; = p.Y2519F on NM_033225.6) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs1271806669, COSV100145723; called by muse, mutect2, varscan2
- CSMD3 | c.8158A>G p.K2720E | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.755); catalogued as COSV99829424; called by muse, mutect2
- CST4 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs774067751, COSV99463147; called by muse, mutect2, varscan2
- CTNNA2 | c.2379C>A p.S793R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100559514; called by muse, mutect2
- CYLC1 | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100254325; called by muse, mutect2
- CYP11A1 | c.656A>T p.Q219L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99165941; called by muse, mutect2, varscan2
- DCC | c.1264A>T p.I422F | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV59109279; called by muse, mutect2, varscan2
- DLX5 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99756336; called by muse, mutect2, varscan2
- DMD | c.6226G>T p.E2076* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as rs398124007, COSV100818785, COSV63784601; called by muse, mutect2, varscan2
- DMD | c.6225G>T p.Q2075H | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV100818788; called by muse, mutect2, varscan2
- DNAH9 | c.7171-2A>T p.X2391_splice | Splice Site (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99304999; called by muse, mutect2, varscan2
- DNAJC28 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.027); catalogued as COSV100074670; called by muse, mutect2, varscan2
- DNMT3A | c.1687G>A p.V563M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs1299203502, COSV53045040; called by muse, mutect2
- DSCAM | c.5165C>G p.S1722* | Nonsense Mutation (SNP) | VAF 25/161 reads (16%) | catalogued as COSV101259604; called by muse, mutect2, varscan2
- DSCAML1 | c.3891T>A p.A1297= (on ENST00000321322; = p.A1237= on NM_020693.4) | Splice Region (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100355323; called by muse, mutect2, varscan2
- DTX3 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99677759; called by muse, mutect2, varscan2
- DYSF | c.2360A>T p.Q787L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM1414216, COSV99245552; called by mutect2, varscan2
- ENAM | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV68536285; called by muse, mutect2
- ERCC4 | c.2177G>C p.R726P | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368096448, COSV100318764; called by muse, mutect2, varscan2
- ERLIN2 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | catalogued as rs1393816662, COSV99379503, COSV99379537; called by muse, mutect2, varscan2
- FAM47A | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.316); catalogued as COSV100649791, COSV60498240; called by muse, mutect2, varscan2
- FAM83B | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.707); catalogued as COSV100174235; called by muse, mutect2, varscan2
- FANCC | c.802T>A p.C268S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs730881718, COSV100002239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCI | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776139524, COSV100167723, COSV55526849; called by muse, mutect2, varscan2
- FAT3 | c.4902G>C p.M1634I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99963809; called by muse, mutect2, varscan2
- FATE1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); catalogued as rs149441058, COSV100948129, COSV64849222; called by muse, mutect2, varscan2
- FBN3 | c.6542G>T p.C2181F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99560380; called by muse, mutect2
- FDXACB1 | c.1644A>T p.K548N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99499642; called by muse, mutect2, varscan2
- FGA | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120213; called by muse, mutect2, varscan2
- FGF12 | c.334G>T p.G112C (on ENST00000454309 / NM_021032.5; = p.G50C on NM_004113.6) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99280062; called by muse, mutect2, varscan2
- FLNA | c.5537A>G p.Y1846C (on ENST00000369850 / NM_001110556.2; = p.Y1838C on NM_001456.3) | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs782771039, COSV100774441; called by muse, mutect2
- FMN2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100144118, COSV60449166; called by muse, mutect2, varscan2
- FMN2 | c.3890A>T p.Y1297F | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100144120; called by muse, mutect2, varscan2
- FMO1 | c.1430G>A p.G477D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100707723; called by muse, mutect2, varscan2
- FOXH1 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs201165974; called by muse, mutect2, varscan2
- FOXRED1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as COSV99702650; called by muse, mutect2, varscan2
- FRMPD1 | c.4055A>T p.E1352V | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV100899473; called by muse, mutect2, varscan2
- FRY | c.3220A>T p.M1074L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs768173822, COSV100968958; called by muse, mutect2, varscan2
- FSCN3 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50000683, COSV99133671; called by muse, mutect2, varscan2
- FYB1 | c.472A>C p.T158P | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100685125; called by muse, mutect2, varscan2
- GABRG1 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV99777653; called by muse, mutect2, varscan2
- GALNT8 | c.1094G>T p.R365M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99362651; called by muse, mutect2, varscan2
- GAS2 | c.869C>A p.T290N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99534882; called by muse, mutect2, varscan2
- GKN2 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV100187743, COSV61030853; called by muse, mutect2, varscan2
- GPHN | c.1196C>G p.P399R (on ENST00000315266 / NM_001377519.1; = p.P432R on NM_020806.5) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100015764; called by muse, mutect2
- GPR26 | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.289); catalogued as COSV99500823; called by muse, mutect2
- GPRASP1 | c.2360A>T p.E787V | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV100850953; called by muse, mutect2, varscan2
- GPRC6A | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV100114195; called by muse, mutect2, varscan2
- GRIK2 | c.1788C>A p.N596K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100024475, COSV100026918; called by muse, mutect2, varscan2
- GRIN2B | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101662981; called by muse, mutect2, varscan2
- GUCY2F | c.2483T>A p.L828* | Nonsense Mutation (SNP) | VAF 25/170 reads (15%) | catalogued as COSV99484711; called by muse, mutect2, varscan2
- GUCY2F | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99484713; called by muse, mutect2, varscan2
- HAVCR1 | c.590C>A p.P197Q | Missense Mutation (SNP) | VAF 52/487 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV100208092, COSV59399359; called by muse, mutect2, varscan2
- HCN1 | c.1958C>A p.T653N | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100299422; called by muse, mutect2, varscan2
- HCRTR2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100904250, COSV63796285; called by muse, mutect2, varscan2
- HIF3A | c.1440G>T p.Q480H (on ENST00000377670 / NM_152795.4; = p.Q411H on NM_022462.4) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV99355645; called by muse, mutect2, varscan2
- HMCN1 | c.10777G>A p.D3593N | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99626435; called by muse, mutect2
- HRNR | c.2744G>A p.R915Q | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372864050, COSV64264076; called by muse, mutect2
- HTR5A | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs1031605672, COSV55283584; called by muse, mutect2, varscan2
- HYDIN | c.6139T>A p.S2047T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.147); catalogued as rs202147256, COSV59263199; called by mutect2, varscan2
- HYDIN | c.529A>T p.T177S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99862472; called by mutect2, varscan2
- IFNAR1 | c.155G>C p.S52T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV99531522; called by muse, mutect2, varscan2
- IGF2R | c.1171C>G p.Q391E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV100807125; called by muse, mutect2, varscan2
- IGFBP5 | c.412del p.R138Gfs*10 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | catalogued as CM067683; called by mutect2, pindel
- IGHV1-18 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs370195764; called by muse, mutect2, varscan2
- IMMT | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as COSV99606202; called by muse, mutect2, varscan2
- IRF6 | c.821T>A p.V274D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100883929; called by muse, mutect2, varscan2
- KAT6A | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV55912283, COSV99704688; called by muse, mutect2, varscan2
- KCND2 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV100474676; called by muse, mutect2, varscan2
- KCNK2 | c.1254G>T p.E418D (on ENST00000444842 / NM_001017425.3; = p.E403D on NM_014217.4) | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV101221981; called by muse, mutect2, varscan2
- KIAA1210 | c.3801G>T p.R1267S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV101274016, COSV68180820; called by muse, mutect2
- KIAA1755 | c.2527C>A p.L843M | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV99641721; called by muse, mutect2, varscan2
- KIF4B | c.2800C>G p.L934V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV101469223, COSV70529951; called by muse, mutect2, varscan2
- LATS1 | c.2884-2A>T p.X962_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99485555; called by muse, mutect2
- LIPA | c.424T>G p.F142V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99260070; called by muse, mutect2, varscan2
- LYST | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as COSV101088766; called by muse, mutect2
- MADD | c.3538A>T p.I1180F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.077); catalogued as COSV100211233; called by muse, mutect2, varscan2
- MAGEB16 | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV101303289; called by muse, mutect2, varscan2
- MAGEB18 | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs964870520, COSV100305389; called by muse, mutect2, varscan2
- MAP3K15 | c.3248C>A p.S1083* | Nonsense Mutation (SNP) | VAF 12/123 reads (10%) | catalogued as COSV100134407; called by muse, mutect2, varscan2
- MARCHF1 | c.221C>A p.P74Q (on ENST00000274056; = p.P57Q on NM_017923.4) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs747981873, COSV56814734; called by muse, mutect2, varscan2
- MAS1 | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1442832403, COSV99396848; called by muse, mutect2, varscan2
- MED12L | c.2626A>G p.T876A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs762301277, COSV99852184; called by muse, mutect2, varscan2
- MEPE | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100734910; called by muse, mutect2, varscan2
- MGAT1 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100286588; called by muse, mutect2, varscan2
- MICAL2 | c.5798G>A p.R1933H | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763336651, COSV56286480; called by muse, mutect2, varscan2
- MKI67 | c.6562G>T p.A2188S | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV100896362; called by muse, mutect2, varscan2
- MORC1 | c.1077C>A p.N359K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV99225530; called by muse, mutect2, varscan2
- MROH2B | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101270605; called by muse, mutect2, varscan2
- MRPL58 | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100042980; called by mutect2, varscan2
- MXRA5 | c.8021C>A p.P2674H | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476119; called by muse, mutect2, varscan2
- MYRF | c.1132C>A p.R378S (on ENST00000278836 / NM_001127392.3; = p.R369S on NM_013279.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV99606786; called by muse, mutect2, varscan2
- NAP1L3 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59076968; called by muse, mutect2, varscan2
- NBEA | c.6504G>T p.K2168N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV59811611; called by muse, mutect2, varscan2
- NID2 | c.3707T>A p.V1236E | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99356195; called by muse, mutect2
- NLRP11 | c.2093G>C p.C698S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV100789688; called by muse, mutect2, varscan2
- NPHP4 | c.4043A>T p.K1348M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100976802; called by muse, mutect2, varscan2
- NPNT | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); catalogued as COSV99974892; called by muse, mutect2, varscan2
- NRXN1 | c.3127G>A p.V1043I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.201); catalogued as rs758678656, COSV100454134; called by mutect2, varscan2
- NTRK2 | c.1492C>A p.P498T (on ENST00000323115 / NM_001369534.1; = p.P514T on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.931); catalogued as COSV52884017, COSV99453896; called by muse, mutect2, varscan2
- NXF1 | c.775A>T p.I259F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99585900; called by muse, mutect2, varscan2
- OBSCN | c.14615T>A p.M4872K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs746503573, COSV99475390; called by muse, mutect2
- OBSCN | c.14616G>T p.M4872I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99475393; called by muse, mutect2
- OPHN1 | c.1316A>T p.D439V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV100830314; called by muse, mutect2, varscan2
- OR2L13 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100813700; called by muse, mutect2
- OR4B1 | c.459C>A p.H153Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100535532; called by muse, mutect2
- OR4D9 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100259765; called by muse, mutect2, varscan2
- OR4X2 | c.835T>A p.Y279N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100183191; called by muse, mutect2, varscan2
- OR51I2 | c.110T>A p.V37E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV100413349; called by muse, mutect2, varscan2
- OR52A1 | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100200449; called by muse, mutect2, varscan2
- OR52L1 | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV100176090; called by muse, mutect2, varscan2
- OR5AR1 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100265611; called by muse, mutect2, varscan2
- OR5D13 | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100686791; called by muse, mutect2, varscan2
- OR5D16 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101003889; called by muse, mutect2, varscan2
- OR6F1 | c.492T>A p.S164R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100129042; called by muse, mutect2, varscan2
- OR6K2 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100656743; called by muse, mutect2, varscan2
- OR9A2 | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV100628192; called by muse, mutect2, varscan2
- OSBPL3 | c.1857C>A p.D619E | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV100513873; called by muse, mutect2, varscan2
- P4HA2 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV99386887, COSV99387242; called by muse, mutect2, varscan2
- PALB2 | c.704C>A p.T235K | Missense Mutation (SNP) | VAF 9/280 reads (3%) | SIFT tolerated (0.92); PolyPhen benign (0.121); catalogued as rs1385914265; ClinVar: uncertain significance; called by muse, mutect2
- PCDH17 | c.2824G>C p.D942H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100931520; called by muse, mutect2, varscan2
- PCDHA2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV100973718, COSV65364724, COSV65365933; called by muse, mutect2, varscan2
- PCDHA2 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100973719; called by muse, mutect2, varscan2
- PCDHA5 | c.2299G>T p.D767Y | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV100972187, COSV65351171; called by muse, mutect2, varscan2
- PCDHB3 | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV99164532; called by muse, mutect2
- PDE2A | c.2434C>A p.Q812K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV57802766; called by muse, mutect2, varscan2
- PDE6A | c.1967A>G p.E656G | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99678051; called by muse, mutect2, varscan2
- PDZD8 | c.1263T>A p.G421= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100559463; called by muse, mutect2, varscan2
- PGBD1 | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as COSV99459930; called by muse, mutect2, varscan2
- PHF20L1 | c.663T>A p.C221* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99620760; called by muse, mutect2, varscan2
- PIK3CG | c.2978T>C p.F993S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV100782734; called by muse, mutect2, varscan2
- PKD2L1 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.159); catalogued as COSV100559343; called by muse, mutect2, varscan2
- PLCZ1 | c.971C>G p.T324R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs769962068, COSV99856082; called by muse, mutect2, varscan2
- PLEC | c.9574G>T p.V3192L (on ENST00000322810 / NM_201380.4; = p.V3082L on NM_000445.5) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100512337; called by muse, mutect2, varscan2
- PLEKHM1 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101378694; called by muse, mutect2, varscan2
- POLR2B | c.714C>G p.S238R | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.155); catalogued as COSV100107945; called by muse, mutect2, varscan2
- POLR3A | c.4066G>T p.G1356* | Nonsense Mutation (SNP) | VAF 22/136 reads (16%) | catalogued as COSV100965585; called by muse, mutect2, varscan2
- POU5F2 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV101232698; called by muse, mutect2, varscan2
- PPP1R3A | c.3277G>T p.D1093Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157758142, COSV99492368; called by muse, mutect2, varscan2
- PPP2CB | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as rs771311551, COSV99646579; called by muse, mutect2, varscan2
- PRDM9 | c.2077G>T p.V693F | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57013462, COSV99690108; called by muse, varscan2
- PRKCB | c.1685A>T p.K562M | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100333008; called by muse, mutect2, varscan2
- PTPRC | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100722305; called by muse, mutect2, varscan2
- PURG | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.636); catalogued as COSV99988608; called by muse, mutect2
- PYROXD1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99556416; called by muse, mutect2, varscan2
- RALGAPA2 | c.5444G>T p.C1815F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99173289; called by muse, mutect2
- RANBP17 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV101206161; called by muse, mutect2
- RERG | c.505C>A p.R169S | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV57000925, COSV99917248; called by muse, mutect2, varscan2
- RNASE2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV58941672; called by muse, mutect2, varscan2
- RNASEH1 | c.649+1del p.X217_splice | Splice Site (DEL) | VAF 6/47 reads (13%) | catalogued as COSV59437986; called by mutect2, varscan2
- ROBO1 | c.1281C>G p.I427M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as COSV101458436, COSV71396006; called by muse, mutect2, varscan2
- ROBO2 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100165303; called by muse, mutect2, varscan2
- ROR1 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as COSV100935105; called by muse, mutect2, varscan2
- RUBCN | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 5/99 reads (5%) | catalogued as rs1422401457, COSV99583584; called by muse, mutect2
- RYR2 | c.3560G>T p.G1187V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100769002; called by muse, mutect2, varscan2
- SCAI | c.431C>G p.T144S (on ENST00000336505 / NM_001144877.3; = p.T167S on NM_173690.5) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV100332415; called by muse, mutect2, varscan2
- SEC31A | c.313A>T p.K105* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100307091; called by muse, mutect2, varscan2
- SERPINA12 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100369622; called by muse, mutect2, varscan2
- SGCZ | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV101167818; called by muse, mutect2, varscan2
- SI | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV100014707; called by muse, mutect2, varscan2
- SIGLEC1 | c.4172G>C p.G1391A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.519); catalogued as COSV99163614; called by muse, mutect2, varscan2
- SIN3A | c.2934G>T p.Q978H | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV100845084; called by muse, mutect2, varscan2
- SIN3A | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100845085; called by muse, mutect2, varscan2
- SLC33A1 | c.1232A>G p.Y411C | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1268248428, COSV100848266; called by muse, mutect2
- SLC39A12 | c.319A>G p.R107G | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782555543, COSV101069814; called by muse, mutect2, varscan2
- SLC39A6 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368552, COSV99309478; called by muse, mutect2, varscan2
- SLC4A4 | c.277C>T p.R93* (on ENST00000264485 / NM_001098484.3; = p.R49* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 15/235 reads (6%) | catalogued as COSV52627802; called by muse, mutect2
- SLC9A4 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as rs189214071, COSV99762847; called by muse, mutect2, varscan2
- SMAD2 | c.977A>C p.E326A | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100053491; called by muse, mutect2, varscan2
- SMARCA4 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as COSV100758300; called by muse, mutect2, varscan2
- SMC3 | c.161G>T p.S54I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100699860, COSV62420698; called by muse, mutect2
- SNAI3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100178804; called by muse, mutect2, varscan2
- SPAG17 | c.3631C>A p.P1211T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100308507; called by muse, mutect2
- SPAG9 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100004812; called by muse, mutect2
- SRCAP | c.55-2A>T p.X19_splice | Splice Site (SNP) | VAF 16/100 reads (16%) | catalogued as COSV99349682; called by muse, varscan2
- SRCAP | c.3564del p.Q1189Sfs*2 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | catalogued as COSV99349658; called by mutect2, pindel, varscan2
- STIM2 | c.435G>T p.L145F | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99402334; called by muse, mutect2, varscan2
- SUSD2 | c.2455G>T p.G819C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV100844239; called by muse, mutect2, varscan2
- SYNE2 | c.5905A>G p.M1969V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs753839811, COSV100647164; called by muse, mutect2, varscan2
- TAF9B | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV100540614; called by muse, mutect2, varscan2
- TAX1BP1 | c.1141G>C p.V381L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as COSV55295666, COSV99604290; called by muse, mutect2, varscan2
- TBC1D9B | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100783467; called by muse, mutect2, varscan2
- TCN1 | c.796C>A p.Q266K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV99953176; called by muse, mutect2, varscan2
- TDP1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100187680; called by muse, mutect2, varscan2
- TFAP2D | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99145797; called by muse, mutect2, varscan2
- THAP4 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); catalogued as rs141722414; called by muse, mutect2, varscan2
- THSD7B | c.891A>G p.I297M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV99747228; called by muse, mutect2
- TLR4 | c.1795C>T p.Q599* (on ENST00000355622 / NM_138554.5; = p.Q559* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100842704; called by muse, mutect2, varscan2
- TLR5 | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as COSV100643231; called by muse, mutect2, varscan2
- TMC1 | c.1991G>A p.C664Y | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52781891, COSV99918999; called by muse, mutect2, varscan2
- TMEM168 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100454570; called by muse, mutect2, varscan2
- TMEM168 | c.1222G>T p.G408* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100454571; called by muse, mutect2, varscan2
- TMEM266 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as COSV101189582; called by muse, mutect2, varscan2
- TRIB2 | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99331009; called by muse, mutect2, varscan2
- TRIM42 | c.1942G>T p.V648L | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV99648169; called by muse, mutect2
- TTC8 | c.300-1G>A p.X100_splice (on ENST00000338104 / NM_001288781.1; = p.X110_splice on NM_144596.4) | Splice Site (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100581187, COSV57629437; called by muse, mutect2
- TTN | c.57856C>T p.R19286C (on ENST00000591111; = p.R11862C on NM_003319.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | PolyPhen probably damaging (0.916); catalogued as rs547604540, COSV60005205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.51846G>T p.M17282I (on ENST00000591111; = p.M9858I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | PolyPhen benign (0.014); catalogued as COSV100602002; called by muse, mutect2, varscan2
- TTN | c.16321C>T p.P5441S (on ENST00000591111; = p.P4514S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | PolyPhen probably damaging (0.951); catalogued as COSV100602005; called by muse, mutect2, varscan2
- TUBGCP3 | c.2236C>G p.H746D | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV99996665; called by muse, mutect2, varscan2
- TXLNA | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 17/126 reads (13%) | catalogued as COSV101009810; called by muse, mutect2, varscan2
- UBR5 | c.2831C>T p.A944V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as rs748984520, COSV55283740; called by muse, mutect2, varscan2
- UCK2 | c.765G>C p.E255D | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100902893; called by muse, mutect2, varscan2
- VRTN | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99832173; called by muse, mutect2, varscan2
- WFDC1 | c.423A>T p.A141= | Splice Region (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99550678; called by muse, mutect2, varscan2
- WIF1 | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99682702; called by muse, mutect2, varscan2
- WWC1 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99514644; called by muse, mutect2, varscan2
- WWC1 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV54649221, COSV99514647; called by muse, mutect2, varscan2
- WWC1 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99514651; called by muse, mutect2, varscan2
- WWP1 | c.1192T>C p.Y398H | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99615972; called by muse, mutect2, varscan2
- XPNPEP1 | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100450911; called by muse, mutect2, varscan2
- ZAP70 | c.1095C>A p.D365E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.703); catalogued as COSV53852599, COSV99385352; called by muse, mutect2, varscan2
- ZC3H6 | c.3184C>A p.L1062I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100674450; called by muse, mutect2, varscan2
- ZDBF2 | c.2797G>C p.D933H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV100984533; called by muse, mutect2, varscan2
- ZFAND3 | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99764814; called by muse, mutect2
- ZFP1 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as COSV100181995; called by muse, mutect2, varscan2
- ZMYM1 | c.3142G>A p.V1048I | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537872338, COSV63254598; called by muse, mutect2, varscan2
- ZNF225 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV99489376; called by muse, mutect2, varscan2
- ZNF3 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as rs182611833, COSV99447157; called by muse, mutect2, varscan2
- ZNF337 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1472458614, COSV99430101; called by muse, mutect2, varscan2
- ZNF451 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100674793; called by muse, mutect2, varscan2
- ZNF451 | c.1964G>T p.C655F | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV100674794; called by muse, mutect2, varscan2
- ZNF626 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.783); catalogued as COSV101656908; called by muse, mutect2
- ZNF682 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.143); catalogued as COSV100653224; called by muse, mutect2, varscan2
- ZP4 | c.403C>A p.R135= | Splice Region (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100850631; called by muse, mutect2, varscan2
- ACVR1B | c.493del p.E165Kfs*69 | Frame Shift Del (DEL) | VAF 23/139 reads (17%) | called by mutect2, pindel, varscan2
- CLCN6 | c.1034del p.G345Afs*10 | Frame Shift Del (DEL) | VAF 40/281 reads (14%) | called by mutect2, varscan2
- DNAH5 | c.12472dup p.R4158Pfs*9 | Frame Shift Ins (INS) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- DSC3 | c.2540_2545del p.D847_Y848del | In Frame Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- DZIP3 | c.2953del p.M985Cfs*19 | Frame Shift Del (DEL) | VAF 42/293 reads (14%) | called by mutect2, pindel, varscan2
- FAM83F | c.1305_1306insG p.R436Efs*31 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel*
- GRIN3A | c.601del p.Q201Rfs*6 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- IGKV1-8 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MMP15 | c.1678del p.Q560Rfs*65 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | called by mutect2, pindel
- MRC1 | c.1806del p.M603* | Frame Shift Del (DEL) | VAF 33/290 reads (11%) | called by mutect2, pindel, varscan2
- MROH1 | c.2897G>A p.G966D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAP1L3 | c.195C>A p.S65R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by mutect2, varscan2
- NFYB | c.423C>G p.F141L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- POTEA | c.1165A>G p.T389A (on ENST00000519951 / NM_001005365.2; = p.T343A on NM_001002920.1) | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- THBS1 | c.140del p.R47Hfs*3 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- TRGV3 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ZMAT4 | c.549del p.T184Qfs*8 | Frame Shift Del (DEL) | VAF 26/257 reads (10%) | called by mutect2, pindel, varscan2
- ACAN | c.384T>A p.S128= | Silent (SNP) | VAF 34/171 reads (20%) | catalogued as COSV100717532; called by muse, mutect2, varscan2
- ACSS3 | c.2034C>T p.H678= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs80307006, COSV99698502; called by muse, mutect2, varscan2
- ADAMTSL4 | c.291C>A p.P97= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99646916; called by muse, mutect2, varscan2
- ADGRL4 | c.1158A>T p.S386= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100875768; called by muse, mutect2
- AKAP9 | c.753G>A p.L251= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100662165; called by muse, mutect2, varscan2
- B3GAT3 | c.72G>T p.L24= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99641903; called by muse, mutect2, varscan2
- C1QTNF3 | c.15G>A p.Q5= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs1450945892, COSV51470150, COSV99180694; called by muse, mutect2, varscan2
- CACNA1F | c.1011C>T p.Y337= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1557110475, COSV100544560; called by muse, mutect2, varscan2
- CCDC70 | c.69C>T p.P23= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV99665328; called by muse, mutect2, varscan2
- CCDC83 | c.555C>A p.I185= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99721563; called by muse, mutect2, varscan2
- CD163 | c.13A>C p.R5= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100775751; called by muse, mutect2, varscan2
- CENPE | c.936T>C p.S312= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1315583554, COSV99477412; called by muse, mutect2, varscan2
- CERKL | c.528A>G p.Q176= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100183408; called by muse, mutect2, varscan2
- CNN1 | c.852C>A p.P284= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV52947419, COSV99370610; called by muse, mutect2, varscan2
- COL2A1 | c.1030C>A p.R344= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as CM034220, COSV100475962, COSV61528796; called by muse, mutect2, varscan2
- COL6A3 | c.909C>G p.A303= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99797039; called by muse, mutect2, varscan2
- COQ8B | c.294G>T p.L98= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99699342; called by muse, mutect2, varscan2
- CRISP2 | c.432G>T p.S144= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100188945; called by mutect2, varscan2
- CSMD2 | c.4425G>C p.V1475= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV99587811; called by muse, mutect2, varscan2
- CSPG4 | c.4320G>A p.L1440= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV100413620; called by muse, mutect2, varscan2
- DLGAP4 | c.423C>T p.H141= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV100211011; called by muse, mutect2, varscan2
- DPP10 | c.1164G>T p.V388= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100061418; called by muse, mutect2, varscan2
- DTWD1 | c.369G>T p.T123= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV52072123, COSV99233556; called by muse, mutect2, varscan2
- ESRP2 | c.1665A>C p.T555= (on ENST00000565858 / NM_001365264.1; = p.T545= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV99251192; called by muse, mutect2
- ESRP2 | c.1044G>A p.V348= (on ENST00000565858 / NM_001365264.1; = p.V338= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99251195; called by mutect2, varscan2
- FBN3 | c.6540C>A p.R2180= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99560382; called by muse, mutect2
- FCHO2 | c.609A>G p.Q203= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99821574; called by muse, mutect2
- GASK1B | c.21G>T p.P7= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99647438; called by muse, mutect2, varscan2
- GGA1 | c.1347A>T p.P449= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100289682; called by muse, mutect2, varscan2
- GPRC6A | c.759C>A p.T253= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100114190; called by muse, mutect2, varscan2
- GRIK4 | c.681C>A p.I227= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs770114291, COSV101483561; called by muse, mutect2, varscan2
- HNF4G | c.48G>T p.G16= (on ENST00000354370 / NM_001330561.2; = p.G63= on NM_004133.5) | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV62968850, COSV62971599; called by muse, mutect2, varscan2
- HPS5 | c.531C>T p.S177= (on ENST00000349215 / NM_181507.2; = p.S63= on NM_007216.4) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100834396; called by muse, mutect2
- HSPA9 | c.1179C>T p.P393= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99785325; called by muse, mutect2
- HTR2C | c.39G>C p.V13= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV99348687; called by muse, mutect2
- IGHV2-26 | c.189G>T p.G63= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs782146717; called by muse, mutect2, varscan2
- IGSF10 | c.6192C>A p.G2064= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV99177241; called by muse, mutect2, varscan2
- IL23R | c.918T>C p.P306= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV100724670; called by muse, mutect2
- ITGAD | c.3039C>A p.P1013= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV99791300; called by muse, mutect2, varscan2
- KRT25 | c.756G>T p.L252= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV100379857; called by muse, mutect2
- LIMA1 | c.786C>A p.L262= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV100372343; called by muse, mutect2, varscan2
- LIPN | c.21A>T p.T7= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV101356216; called by muse, mutect2, varscan2
- LRRTM4 | c.1215C>G p.S405= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV101297477; called by muse, mutect2, varscan2
- MACO1 | c.1962C>T p.P654= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs1459503159, COSV100975077; called by muse, mutect2, varscan2
- MIA2 | c.561A>T p.V187= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV99697458; called by muse, mutect2, varscan2
- MRC2 | c.1290C>G p.T430= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100316013; called by muse, mutect2, varscan2
- MRPS26 | c.588G>C p.L196= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99848620; called by muse, mutect2, varscan2
- MUC16 | c.18390C>A p.S6130= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV101197562, COSV101199050; called by muse, mutect2, varscan2
- MYO10 | c.5481C>A p.L1827= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99945009; called by muse, mutect2
- NALCN | c.3648C>A p.I1216= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV51953973; called by muse, mutect2, varscan2
- NCOA1 | c.1167G>T p.S389= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV99945615; called by muse, mutect2, varscan2
- NEU4 | c.1410G>T p.P470= (on ENST00000391969 / NM_001167602.3; = p.P482= on NM_080741.4) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs373801719, COSV100371916; called by muse, mutect2, varscan2
- NLRP3 | c.2034C>A p.S678= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100275631; called by muse, mutect2, varscan2
- NLRP4 | c.636C>T p.P212= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs771374690, COSV56712458; called by muse, mutect2, varscan2
- OR2T11 | c.63C>A p.A21= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV100424738; called by muse, mutect2, varscan2
- OR4A15 | c.141C>T p.I47= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as rs377665149, COSV100123935; called by muse, mutect2, varscan2
- OR52A5 | c.858C>A p.V286= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100263345; called by muse, mutect2, varscan2
- OR56B1 | c.111T>A p.S37= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100402573; called by muse, mutect2, varscan2
- OR5D18 | c.84C>A p.L28= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV100450592, COSV61736049, COSV61738497; called by muse, mutect2, varscan2
- OR5T3 | c.873A>G p.T291= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV100282742; called by muse, mutect2, varscan2
- OR7A17 | c.483A>G p.L161= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV100541588; called by muse, mutect2, varscan2
- PCDHB12 | c.663C>A p.P221= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV53396285, COSV99507017; called by muse, mutect2, varscan2
- PGK2 | c.276T>C p.D92= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as COSV100505392; called by muse, mutect2, varscan2
- PKHD1 | c.11406C>A p.T3802= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100944090; called by muse, mutect2
- PLAU | c.114A>G p.T38= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV101032283; called by muse, mutect2, varscan2
- PLEC | c.7269G>A p.A2423= (on ENST00000322810 / NM_201380.4; = p.A2313= on NM_000445.5) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs200335976, COSV100512339; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRUNE2 | c.3669C>A p.V1223= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100944348; called by muse, mutect2, varscan2
- RAB30 | c.513C>T p.I171= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV99475534; called by muse, mutect2, varscan2
- RAB37 | c.522C>A p.A174= (on ENST00000392613 / NM_001006638.3; = p.A167= on NM_175738.5) | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99379931; called by muse, mutect2
- RELN | c.927C>T p.I309= | Silent (SNP) | VAF 38/210 reads (18%) | catalogued as COSV100633007; called by muse, mutect2, varscan2
- RGR | c.621G>T p.L207= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100812877; called by muse, mutect2, varscan2
- RIMS2 | c.3918G>A p.E1306= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99165160; called by muse, mutect2, varscan2
- ROBO1 | c.3951C>T p.P1317= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101458434; called by muse, mutect2
- RUBCN | c.555G>A p.Q185= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99583588, COSV99584086; called by muse, mutect2, varscan2
- SLC30A6 | c.1041A>T p.A347= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99249504; called by muse, mutect2
- SNCAIP | c.618A>T p.P206= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV99747890; called by muse, mutect2
- TBL1X | c.465T>A p.A155= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99482328; called by muse, mutect2, varscan2
- TIAM1 | c.639G>T p.G213= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs745482555, COSV99733921; called by muse, mutect2
- TM4SF20 | c.450T>C p.S150= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100460014; called by muse, mutect2, varscan2
- TMEFF2 | c.87A>G p.L29= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs776190134, COSV99771266; called by muse, mutect2, varscan2
- TMEM182 | c.474C>A p.I158= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV101305352; called by muse, mutect2, varscan2
- TPTE | c.1050T>C p.C350= (on ENST00000618007 / NM_199261.4; = p.C332= on NM_199259.4) | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- TRIM51 | c.906G>C p.L302= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV99792351; called by muse, mutect2, varscan2
- TRPA1 | c.2265T>C p.T755= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100083611; called by muse, mutect2, varscan2
- U2SURP | c.2733C>T p.D911= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV101204399; called by muse, mutect2
- UBXN10 | c.15C>T p.A5= | Silent (SNP) | VAF 13/169 reads (8%) | catalogued as COSV100907755; called by muse, mutect2
- USH2A | c.3729C>T p.P1243= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs1277398294, COSV100231895; called by muse, mutect2, varscan2
- VEZF1 | c.474A>G p.P158= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs760657819, COSV99365635; called by muse, mutect2, varscan2
- XAGE2 | c.117A>T p.P39= | Silent (SNP) | VAF 22/184 reads (12%) | called by muse, mutect2, varscan2
- XAGE3 | c.234T>G p.T78= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100655646; called by muse, mutect2, varscan2
- ZNF536 | c.393G>T p.P131= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1237534768, COSV62818514, COSV62831779; called by muse, mutect2, varscan2
- BMP1 | c.2107+1841del | Intron (DEL) | VAF 23/117 reads (20%) | catalogued as rs1563271510; called by mutect2, pindel, varscan2
- EI24P4 | n.952C>T | RNA (SNP) | VAF 15/268 reads (6%) | called by muse, mutect2
- IGKV1-13 | n.139G>T | RNA (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- MIR129-2 | n.89C>A | RNA (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- SPINK5 | c.2740-142C>T | Intron (SNP) | VAF 14/66 reads (21%) | catalogued as rs763774354, COSV56249204, COSV56263547; called by muse, mutect2, varscan2
- SSPOP | n.7085G>C | RNA (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100022278, COSV50489555; called by muse, mutect2, varscan2
- TMEM99 | n.576G>A | RNA (SNP) | VAF 22/225 reads (10%) | catalogued as rs1003358269, COSV100054018; called by muse, mutect2, varscan2
- XIRP2 | c.*1139G>T | 3'UTR (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99740610; called by muse, mutect2, varscan2
